Gene-level copy-number profile of tumor specimen TCGA-BL-A13J-01A from TCGA case TCGA-BL-A13J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.5 years (23,927 days).
Specimen TCGA-BL-A13J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.1d160de2-9c94-4172-9934-aad4322a5141.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BL-A13J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41f4f488-dbab-451c-bc72-64812ee120b4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 688; copy number 2: 7,139; copy number 3: 22,691; copy number 4: 14,065; copy number 5: 6,568; copy number 6: 4,865; copy number 7: 1,370; copy number 8: 965; copy number 9: 235; copy number 10: 464; copy number 13: 89; copy number 14: 65; copy number 15: 148; copy number 16: 87; copy number 18: 67; copy number 20: 82; copy number 23: 122; copy number 26: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BL-A13J-01A-11D-A273-01): tumor purity 0.56, ploidy 3.59, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 25 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,929,457–23,898,054, 24 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,766 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,127,287–194,198,708, 745 genes, copy number 10–26 (broad region; genes not listed).
- chr7:79,335,780–81,199,115, 22 genes, copy number 7: AC074024.1, RNU6-530P, AC004945.1, MAGI2-AS3, NUP35P2, RNA5SP234, AC073048.1, GNAI1, RNU6-849P, RPL10P11, RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1, AC005008.2, AC005008.1.
- chr7:85,636,013–89,754,726, 40 genes, copy number 7: AC092013.1, SOCS5P1, GRM3, AC005009.1, GRM3-AS1, ELAPOR2, AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9, RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1, ZNF804B, TEX47, AC002383.1, RNU6-274P.
- chr7:127,652,194–152,025,472, 644 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:104,590,733–105,804,539, 1 gene, copy number 8 (within-gene range 6–8): ZFPM2.
- chr8:105,142,860–106,272,902, 12 genes, copy number 8: AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2.
- chr9:25,676,389–29,826,711, 41 genes, copy number 9: TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:38,949,734–43,045,120, 117 genes, copy number 7 (broad region; genes not listed).
- chr10:38,094,368–38,360,098, 1 gene, copy number 7 (within-gene range 6–7): AL117339.4.
- chr10:38,247,922–48,445,820, 196 genes, copy number 7 (broad region; genes not listed).
- chr11:62,169,293–62,740,293, 41 genes, copy number 8 (within-gene range 6–8): EEF1DP8, SCGB1D1, SCGB2A1, AP003306.1, SCGB1D2, SCGB2A2, SCGB1D4, NPM1P35, AP003306.2, ASRGL1, RCC2P6, AP003064.1, SCGB1A1, AP003064.2, AHNAK, AP001363.1, AP001363.2, EEF1G, AP002990.1, MIR6747, TUT1, MTA2, EML3, AP001458.1, ROM1, B3GAT3, GANAB, INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C.
- chr11:69,641,156–72,080,693, 78 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr11:120,511,746–135,075,908, 304 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:24,810,024–24,949,101, 1 gene, copy number 10 (within-gene range 3–10): BCAT1.
- chr12:24,902,309–29,381,189, 97 genes, copy number 10–14 (within-gene range 6–14) (broad region; genes not listed).
- chr12:30,086,342–31,201,235, 23 genes, copy number 7: AC023511.3, AC023511.2, AC023511.1, LINC02386, AC078776.2, RNA5SP356, AC078776.1, AC026371.1, IPO8, AC012673.1, CAPRIN2, AC010198.1, LINC00941, AC010198.2, PPIAP44, TSPAN11, AC008013.1, AC008013.2, DDX11-AS1, DDX11, SNORA75, AC008013.3, AC024940.1.
- chr13:30,973,289–31,332,276, 6 genes, copy number 9 (within-gene range 5–9): AL353680.1, LINC01066, AL158065.1, WDR95P, HSPH1, B3GLCT.
- chr15:69,160,584–76,980,451, 229 genes, copy number 8–20 (within-gene range 3–20) (broad region; genes not listed).
- chr15:81,324,338–81,518,200, 1 gene, copy number 10 (within-gene range 3–10): TMC3-AS1.
- chr15:81,403,026–82,739,122, 35 genes, copy number 10: AC109809.1, AC060809.1, AC023034.1, AC104041.1, AC026956.1, MEX3B, LINC01583, AC026956.2, EFL1, RNU1-77P, AC026624.1, SAXO2, ADAMTS7P1, GOLGA6L10, UBE2Q2P2, AC243919.1, AC243919.2, GOLGA6L9, UBE2Q2P6, CSPG4P10, AC245033.3, GOLGA2P10, GOLGA6L17P, DNM1P38, AC245033.4, RPS17, AC245033.1, AC245033.2, CPEB1, CPEB1-AS1, AP3B2, AC105339.4, AC105339.1, ACTG1P17, AC105339.5.
- chr16:24,400,056–29,973,050, 183 genes, copy number 9 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 8 (broad region; genes not listed).
- chr22:22,871,507–26,780,893, 176 genes, copy number 8–15 (broad region; genes not listed).
- chr22:46,150,521–48,143,229, 28 genes, copy number 7: PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1.

Autosomal genes at a single copy (total copy number 1): 118. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
